Surgical pathology report (de-identified scan), TCGA case TCGA-49-AAR3, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AAR3-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

- 1) STATION R-4 (EXCISION): FOUR (4) LYMPH NODES NEGATIVE FOR TUMOR.
- 2) STATION 7 (EXCISION): THREE (3) LYMPH NODES NEGATIVE FOR TUMOR.
- 3) LOWER R-4 (EXCISION): ONE (1) LYMPH NODE NEGATIVE FOR TUMOR.
- 4) STATION R-11 (EXCISION): ONE (1) LYMPH NODE NEGATIVE FOR TUMOR.
- 5) STATION R-10 (EXCISION): METASTATIC CARCINOMA PRESENT IN ONE OF ONE (1/1) LYMPH NODE.
- 6) LUNG, RIGHT UPPER LOBE (LOBECTOMY):

SPECIMEN TYPE:

Lobectomy

TUMOR SITE:

Right upper lobe

HISTOLOGIC TYPE:

Adenocarcinoma, NOS. SEE NOTE

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: R Lung, upper lobe C34.1
JW 5/24/14

NOTE: Immunostains show that the neoplastic cells are positive for TTF-1 and CK7, negative for CK20, S-100, and calretinin, supporting the diagnosis of adenocarcinoma, while against the diagnosis of malignant mesothelioma or melanoma. This case was shown at the

TUMOR SIZE:

3.0 cm greatest dimension

HISTOLOGIC GRADE:

G3: Poorly differentiated

LYMPH NODES:

Metastatic carcinoma in 1 of 13 lymph nodes
(see part 5)

(Continued on next page.)

[page 2 of 6]
=====

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor which is > or = 3 cm

REGIONAL LYMPH NODES:

pN1: Metastasis in ipsilateral peribronchial, hilar,
or intrapulmonary nodes, including those involved
by direct extension

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins uninvolved by invasive carcinoma

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

Venous invasion present

LYMPHATIC (SMALL VESSEL) INVASION:

Present

7) STATION 7 (EXCISION): THREE (3) LYMPH NODES NEGATIVE FOR TUMOR.

8) PLEURAL PLAQUE (EXCISION): DENSE FIBROUS TISSUE, NEGATIVE FOR
TUMOR.

*Electronic signature

Some stains/tests used in arriving at the diagnosis were performed
here using reagents that have not been cleared or approved by the
US Food and Drug Administration. These were developed and their
performance characteristics determined by the

Their use does not require FDA approval.

=====

Clinical History:

LUNG CANCER

(Continued on next page.)

[page 3 of 6]
=====

GROSS DESCRIPTION

PART #1: FS: R-4
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists / PAs:

FS: R-4: Four (4) lymph node, negative for tumor.

Dictated by:

The specimen is received fresh labeled [REDACTED] and designated "R-4". It consists of four (4) red to black nodules, measuring in aggregate 1.5 x 0.8 x 0.3 cm. The specimen is submitted in its entirety for FSC.

SUMMARY OF SECTIONS:

1 - FSC - 4
1 - TOTAL - 4

PART #2: STATION 7
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists / PAs:

FS: Station 7: Three (3) lymph nodes, negative for tumor.

Dictated by:

The specimen is received fresh labeled [REDACTED] and designated "station 7". It consists of three (3) red to black nodules measuring in aggregate 1.0 x 1.0 x 0.4 cm. The specimen is submitted in its entirety for FSC.

SUMMARY OF SECTIONS:

1 - FSC - 3

(Continued on next page.)

[page 4 of 6]
=====

1 -TOTAL - 3

PART #3: LOWER R-4
Resident Pathologist:

Dictated by: (Parts 3-8).

The specimen for Part 3 is received fresh, labeled with the patient's name, [REDACTED] and designated "Lower R4." The specimen consists of one (1) piece of red-tan-brown soft tissue measuring 1.8 x 1.0 x 1.0 cm. Fifty percent (50%) of the specimen is submitted to be saved for possible future studies. The remaining fifty percent (50%) of the specimen is submitted for permanent sections.

SUMMARY OF SECTIONS :

1 - A - 1
1 - TOTAL - 1

PART #4: R-11
Resident Pathologist:

The specimen for Part 4 is received fresh, labeled with the patient's name, [REDACTED] and designated "R11." The specimen consists of one (1) piece of red to tan to brown soft tissue measuring 1.5 x 0.9 x 0.7 cm. Fifty percent (50%) of the specimen is preserved for possible future studies and the remaining fifty percent (50%) is submitted in its entirety.

SUMMARY OF SECTIONS :

1 - A - 1
1 - TOTAL - 1

(Continued on next page.)

[page 5 of 6]
PART #5: R-10
Resident Pathologist:

The specimen for Part 5 is received fresh, labeled with the patient's name, [REDACTED], and designated "R10." The specimen consists of one (1) piece of red to tan to brown soft tissue measuring 2.0 x 1.5 x 1.1 cm. Fifty percent (50%) of the specimen is preserved for possible future studies. The remaining fifty percent (50%) is submitted in its entirety.

SUMMARY OF SECTIONS :

1 - A - 1
1 - TOTAL - 1

PART #6: RIGHT UPPER LOBE
Resident Pathologist:

The specimen for Part 6 is received fresh, labeled with the patient's name, [REDACTED], and designated "Right Upper Lobe." The specimen consists of a 186.0 gram right lobectomy measuring 16.2 x 10.0 x 2.7 cm. The lung is diffusely noncrepitant. The pleura is hemorrhagic and mottled with anthracotic pigmentation. Located in the outer aspect of the lobe is a tan, white, firm 3.0 x 2.5 cm ill defined mass. The mass does not appear to ulcerate the pleura; however, it does closely approximate the pleura to within 0.1 cm. The area around the tumor is inked orange. Tissue from the tumor is harvested for future studies. The tumor mass is over 3.0 cm away from the bronchial margin, but does closely approximate a bronchiole, and this is submitted in representative sections. The remaining airways are unremarkable, with tan, glistening mucosa. The vascular margins and bronchial margins are removed as shaved margins; the staple line is removed, and the underlying parenchyma is inked black. The lung is serially sectioned, and the remaining lung tissue is congested, red to brown, with focal emphysematous changes and generalized anthracotic pigmentation. Hilar vessels are unremarkable. No hilar nodes are identified. Representative sections are submitted of the tumor as well as normal lung.

SUMMARY OF SECTIONS :

1 - A - 4 (BRONCHIAL AND VASCULAR MARGINS)

(Continued on next page.)

[page 6 of 6]
=====

1 - B	- 1	(PLEURAL MARGIN)
1 - C	- 1	(PLEURAL MARGIN)
1 - D	- 1	(TUMOR TO BRONCHIAL)
1 - E	- 1	(TUMOR TO NORMAL)
2 - F,G	- 1 EA	(NORMAL LUNG)
1 - H	- 1	(PARENCHYMAL MARGIN)
8 - TOTAL	- 11	

PART #7: STATION 7
Resident Pathologist:

The specimen for Part 7 is received fresh, labeled with the patient's name, [REDACTED], and designated "Station 7." The specimen consists of three (3) pieces of red to tan to black soft tissue measuring 2.0 x 2.0 x 0.7 cm. Twenty-five percent (25%) of the tissue is harvested for possible future studies. The remaining seventy-five percent (75%) of the specimen is submitted.

SUMMARY OF SECTIONS :
2 - A,B - 1 EA
2 - TOTAL - 2

PART #8: PLEURA PLAQUE
Resident Pathologist:

The specimen for Part 8 is received fresh, labeled with the patient's name, [REDACTED], and designated "Pleural Plaque." The specimen consists of two (2) pieces of white, firm tissue measuring 1.3 x 0.5 x 0.4 cm in aggregate. The specimen is submitted in its entirety for light decalcification.

SUMMARY OF SECTIONS :
1 - A - 2
1 - TOTAL - 2

=====

(End of Report)

printed

Criteria	hw 1/18/14	Yes	No

Source: NCI Genomic Data Commons file 0207a1ff-a816-416e-9d55-8063654db914 (TCGA-49-AAR3.75D3436D-1CF9-4DC9-97EE-B93E2D6A3049.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).